Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4836, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4836-01A (Primary Tumor).

TCGA-B0-4836

FINAL DIAGNOSIS:

RIGHT KIDNEY AND ADRENAL GLAND, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN'S GRADE 3 OF 4 WITH FOCI OF NECROSIS AND HEMORRHAGE, INVOLVING THE MID PORTION OF THE KIDNEY.
- B. THE TUMOR IS 2.8 CM IN GREATEST DIMENSION.
- C. THE CARCINOMA INVOLVES THE RENAL CORTEX AND MEDULLA AND EXTENDS INTO THE ADIPOSE TISSUE IN THE RENAL SINUS.
- D. VASCULAR INVASION IS PRESENT, INCLUDING A TUMOR THROMBUS IN A LARGER BRANCH OF THE RENAL VEIN IN THE RENAL HILUM BUT THE MAIN RENAL VEIN AT THE SURGICAL MARGIN IS FREE OF TUMOR (slide D and K).
- E. BENIGN URETER SEGMENT, RENAL ARTERY AND GEROTA'S FASCIA.
- F. ALL SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- G. NO SIGNIFICANT PATHOLOGIC CHANGES ARE SEEN IN THE NON-NEOPLASTIC KIDNEY AWAY FROM THE TUMOR.
- H. PORTION OF BENIGN, HISTOLOGICALLY UNREMARKABLE ADRENAL GLAND.
- I. PATHOLOGIC TNM STAGE: pT3b Nx M1 (see comment).

COMMENT:

Please cross refer to cases [REDACTED] and [REDACTED] which show probable metastatic renal cell carcinoma to the lung.

Source: NCI Genomic Data Commons file fc497433-4ef0-424d-8a6f-5e6b31ec8696 (TCGA-B0-4836.6AA4709B-7F20-4632-83E4-25A74588BDCA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).